Surgical pathology report (de-identified scan), TCGA case TCGA-09-1670, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1670-01A (Primary Tumor).

[page 1 of 6]
FINAL PATHOLOGIC DIAGNOSIS

■ Left ovary and fallopian tube, salpingo-oophorectomy:

- Ovary: Poorly differentiated serous carcinoma, see comment.
- Fallopian tube: Metastatic serous carcinoma in fimbriae.

Fibrosis of tubal plicae.

B. Right ovary and fallopian tube, salpingo-oophorectomy:

- Ovary:

1. Poorly differentiated serous carcinoma.
2. Hemorrhage, necrosis, fibrosis, foreign body giant cell reaction and

histiocytic reaction at previous cystectomy site.

- Fallopian tube: Fibrosis of tubal plicae. Endometriosis.

- Adnexal peritoneum and soft tissue:

1. Microscopic foci of serous carcinoma in peritoneum.
2. Fat necrosis, fibrosis and chronic inflammation.

C. Lymph nodes, right pelvic, dissection: No evidence of carcinoma in eleven lymph nodes (0/11).

D. Lymph nodes, left pelvic, dissection: No evidence of carcinoma in ten lymph nodes (0/10).

E. Uterus and cervix, total abdominal hysterectomy:

- Cervix: No significant pathologic abnormality.
- Endometrium: Inactive pattern; benign endometrial polyp.
- Myometrium: Leiomyoma; adenomyosis.
- Serosa: No significant pathologic abnormality.
- Parametrium: Metastatic serous carcinoma on serosal surface.

Page 1 of 5

F. Diaphragm, biopsy: Metastatic serous carcinoma.

G. Omentum, omentectomy: No significant pathologic abnormality, no evidence of carcinoma.

H. Lymph nodes, right periaortic, dissection:

1. No evidence of carcinoma in eleven lymph nodes (0/11).
2. Hemosiderosis.

I. Lymph nodes, mid line periaortic, dissection:

1. No evidence of carcinoma in four lymph nodes (0/4).
2. Benign lipogranulomas.

J. Lymph nodes, left periaortic, dissection: No evidence of carcinoma in six lymph nodes (0/6).

K. Ileum and cecum, right colectomy:

[page 2 of 6]
- 1. Subserosal fibrosis.**
- 2. Metastatic serous carcinoma in areas of subserosal fibrous scar.**
- 3. Ileocecal adhesions with hemorrhage, fat necrosis and chronic inflammation.**
- 4. No evidence of carcinoma in five mesenteric lymph nodes (0/5).**

COMMENT:***Ovarian Tumor Synoptic Comment***

1. Type of tumor: Carcinoma, serous.
2. Grade of tumor: 3.
3. Location of tumor: Bilateral.
4. Diameter of tumor: 7.5 cm on the right and 7.7 cm greatest dimension of aggregate of disrupted fragments on the left.
5. Appearance of surface of ovary: Smooth on right, fragmented on left.
6. Condition of capsule: Intact on the right, disrupted on the left.
7. Appearance of cut surface: Solid and cystic, mainly cystic on the right. Solid on the left.
8. Color of solid areas: Tan and gold.
9. Necrosis: None present.
10. Lymphatic/vascular invasion: Not present.
11. Sites of metastases in pelvis: Fimbriated end of right fallopian tube, right parametrium.
12. Pelvic lymph nodes: Negative. Total twenty-one nodes examined, all of which are negative.
13. Sites of metastases in abdomen: Diaphragm and serosa of bowel.
14. Para-aortic lymph nodes: Negative. Total twenty-one nodes examined, all of which are negative.
15. Peritoneal cytology: Pelvic washing. Cytology accession number [REDACTED] positive.
16. Other significant findings: Endometriosis.
17. FIGO stage: 3A.
18. TNM stage: pT3aN0MX.
- An atypical area was identified in slide C5 of the right pelvic lymph node dissection. An immunohistochemical stain for keratin was performed and examined at [REDACTED] to help establish the diagnosis.
- Keratin: Negative.
- The negative staining for keratin rules out the presence of a lymph node metastasis in slide C5. It is possible that this represents vascular transformation of the lymph node sinus, a benign condition. We will investigate it further and report the results in an addendum.
- Page 2 of 5

[page 3 of 6]
Specimen(s) Received

A: Left ovary and tube
B: Right ovary and tube
C: Right pelvic lymph nodes (fresh)
D: Left pelvic lymph nodes (fresh)
E: Uterus and cervix (fresh)
F: Diaphragm biopsy
G: Omentum
H: Right periaortic lymph node
I: Midline periaortic lymph node
J: Left periaortic lymph node
K: Ileum and colon (cecum)

Intraoperative Diagnosis

FS1 (A) Left ovary and tube, salpingo-oophorectomy: Invasive carcinoma, endometrioid type. Inked margin positive.

FS2 (B) Right ovary and tube, salpingo-oophorectomy: Positive for carcinoma.

Clinical History

The patient is a . Rule out ovarian cancer. No other history is provided. History from STOR indicates that she had an incidental right ovarian cyst found at the time of appendectomy. This was resected and showed moderately differentiated endometrioid cancer and normal fallopian tube. She now undergoes staging laparotomy, total abdominal hysterectomy, omentectomy, and ileocecal resection.

Gross Description

The specimen is received in eleven parts, each labeled with the patient's name and medical record number.

Parts A-E are received fresh. Parts F-K are received in formalin.

Part A, labeled "left tube and ovary frozen section," consists of a large cyst with no grossly identifiable ovary weighing 165 gm and measuring 7.5 x 6.5 x 5 cm, intact. The surface is smooth and is inked black. There is a fallopian tube (4 x 0.5 x 0.5 cm) and the fimbria is attached to the mass by adhesions. The cyst contains 120 cc of watery brown fluid. The cyst is composed of a multiloculated, partially solid consistency. The deflated cyst measures 5 x 6.5 x 1.2 cm and weighs 24 gm. Approximately 25% of the cyst is solid, composed of a soft, white-tan, solid component or a fibrous, brown, solid component. The rest of the cyst is multicystic with the cysts containing golden yellow, papillary outgrowths on the inner surface.

The tumor does not grossly invade the capsule. Representative sections are taken for intraoperative

diagnosis as frozen section 1, with the frozen section remnant submitted in cassette

[page 4 of 6]
[REDACTED]

A1. Further

representative sections are taken as follows:

Cassette A2: Solid and brown fibrous interface.

Cassette A3: Solid and brown fibrous interface.

Cassette A4: Papillary outgrowths on cystic lining.

Cassette A5: Brown fibrous areas.

Cassette A6: ?Residual ovary and fallopian tube.

Part B, labeled "right tube and ovary," consists of multiple soft, fragmented, irregular pieces of

pink-red-purple tissue weighing 31.2 gm and measuring 7.7 x 5.6 x 2 cm in aggregate. The largest

fragmented piece consists of multiple papillary outgrowths attached to a smooth lining suspended from the

fallopian tube. The fallopian tube measures 4.5 x 0.5 x 0.5 cm and is hemorrhagic.

Using the fallopian

tube for orientation, the papillary areas are present on a fragment of cyst wall that corresponds to the

inside surface of the cystic mass, although exact orientation is not possible. In

addition to this, there are

multiple, separate fragments measuring 3.5 x 3.5 x 1 cm in aggregate. On serial

sectioning, these are

composed of yellow and white adipose tissue with small areas of white-tan fibrinous exudate. A random

Page 3 of 5

representative section is submitted for intraoperative diagnosis as frozen section 2, with the frozen section

remnant submitted in cassette B1. Further representative sections are taken as follows:

Cassette B2: Attachment of the mass to the fallopian tube.

Cassette B3: Papillary outgrowths and cyst wall.

Cassette B4: Papillary outgrowths and normal fallopian tube.

Cassette B5: Sections of adipose tissue.

Part C, labeled "right pelvic lymph nodes," consists of an aggregate of golden yellow fatty tissue and fibrous

tissue measuring 6.5 x 6 x 2 cm. The fatty tissue is dissected off and representative lymph nodes are

submitted as follows:

Cassette C1: Three candidate lymph nodes.

Cassette C2: Two candidate lymph nodes.

Cassette C3: Three candidate lymph nodes.

Cassettes C4-C5: A single, 3.5 cm in greatest dimension lymph node, bisected.

Part D, labeled "left pelvic lymph nodes," consists of an aggregate of golden yellow fatty tissue and fibrous

tissue measuring 5 x 3.5 x 1.5 cm. The fatty tissue is dissected off and candidate lymph nodes are

submitted as follows:

Cassette D1: Three candidate lymph nodes.

Cassette D2: Four candidate lymph nodes.

Cassette D3: Four candidate lymph nodes.

Cassette D4: Single lymph node, bisected.

Part E, labeled "uterus and cervix," consists of a uterus with attached cervix consists of adnexa weighing

TCGA-09-1670

[page 5 of 6]
54.6 gm. The uterus measures 7.5 cm from fundus to cervix, 3.2 cm from cornu to cornu and 2 cm from anterior to posterior. It is oriented by the peritoneal reflections. In addition, there is attached partial right parametrium, measuring 5 x 3 x 1 cm. The serosa is smooth. The uterus sounds to 6 cm. The cervix measures 3 cm in width, 3.5 cm in length, has a fish-mouthed os measuring 1.2 cm in width. The uterus is opened along the lateral borders. The transition zone and endocervical canal are unremarkable. The endometrium is tan and measures 0.3 cm. There is a polyp on the anterior endometrial surface, measuring 0.5 cm in greatest dimension. In addition, there is a 0.8 cm leiomyoma on the anterior myometrium. The myometrium measures 1.1 cm. Representative sections are submitted as follows:
Cassette E1: Anterior cervix.
Cassettes E2-E3: Posterior cervix.
Cassette E4: Polyp, (entirely submitted), and anterior endomyometrium.
Cassette E5: Posterior endomyometrium.
Cassette E6: Right parametrium.
Part F is additionally labeled "diaphragm biopsy." It consists of two small, unoriented, white-tan, soft tissue fragments measuring 1 x 1 x 0.1 cm in aggregate. It is entirely submitted in cassette F1.
Part G is additionally labeled "omentum." It consists of a single piece of fatty tissue measuring 15 x 13 x 3 cm and weighing 311 grams. It is serially sectioned. No abnormalities are detected. Representative sections are submitted in cassettes G1-G3.
Part H is additionally labeled "right periaortic lymph node." It consists of a piece of fibrofatty tissue measuring 4.5 x 1.5 x 0.5 cm. The fibrofatty tissue is dissected off and candidate lymph nodes are submitted as follows:
Cassette H1: Four candidate lymph nodes.
Cassette H2: Single lymph node, bisected.
Cassette H3: Two candidate lymph nodes.
Part I is additionally labeled "mid line periaortic lymph node." It consists of a single piece of fibrofatty tissue measuring 4.8 x 2 x 0.3 cm. The fatty tissue is dissected off and four candidate lymph nodes are submitted in cassette I1.
Part J is additionally labeled "left periaortic lymph node." It consists of a single piece of fibrofatty tissue

Page 4 of 5

measuring 4 x 2 x 1.2 cm. The fatty tissue is dissected off and submitted as follows:
Cassette J1: Four candidate lymph nodes.
Cassette J2: Two candidate lymph nodes.
Cassette J3: Single lymph node, bisected.
Part K is additionally labeled "ileum and colon (cecum)." It consists of a 21-cm length of terminal ileum and cecum which is received intact. The proximal staple margin is inked blue, the distal

[page 6 of 6]
[REDACTED]

staple margin is inked black. On opening the specimen consists of a piece of terminal ileum measuring 11 cm, the ileocecal valve, which is patent and a 9-cm cecal pouch. No abnormalities are visualized on the mucosal aspect. No masses are identified. On the serosal aspect, there is a mild area of adhesion between the cecum and the terminal ileum. This extends to the surrounding mesentery. The mucosal surfaces appear normal. No appendix is visualized. The mesentery is searched for lymph nodes; however, none are identified.

Representative sections are submitted as follows:

Cassette K1: Terminal ileum and cecal margin.

Cassette K2: Area of serosal adhesion.

Cassette K3: Ileocecal valve.

Cassette K4: Further representative section through cecum and terminal ileum.

Cassettes K5-K6: Representative sections of mesentery.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

Source: NCI Genomic Data Commons file dd8e4ff4-28d9-4dec-98bf-bc545c7511e4 (TCGA-09-1670.5CC85CD9-99C4-4087-BDC5-8039B0369538.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).